Gene-level copy-number profile of tumor specimen HTMCP-03-06-02013-01B from CGCI case HTMCP-03-06-02013, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3; Age at diagnosis: 50.8 years (18,551 days).
Specimen HTMCP-03-06-02013-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 357c4172-04c3-4042-9b00-9fdb6a6f5ede.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02013-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/f0a087e7-58f7-4afc-b180-b3e7d091b889

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 3,509; copy number 2: 37,239; copy number 3: 12,216; copy number 4: 5,196; copy number 5: 185; copy number 9: 2; copy number 10: 1; copy number 16: 1; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,525,989–20,526,751, 1 gene: RPS4XP4.
- chr1:120,419,850–120,467,739, 1 gene (within-gene range 0–1): NBPF8.
- chr1:120,489,860–121,009,291, 12 genes (within-gene range 0–1): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4.
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr2:111,771,061–111,771,134, 1 gene (within-gene range 0–2): MIR4771-2.
- chr2:140,898,423–140,899,106, 1 gene (within-gene range 0–2): LRRC57P1.
- chr11:126,423,358–127,172,363, 10 genes (within-gene range 0–1): KIRREL3, KIRREL3-AS1, AP001783.1, AP002833.1, AP002833.3, KIRREL3-AS2, MIR3167, AP002833.2, KIRREL3-AS3, AP001993.1.
- chr15:74,489,602–74,516,959, 2 genes (within-gene range 0–2): AC012435.3, AC012435.1.
- chr16:32,600,299–32,622,184, 2 genes: AC137800.1, AC137800.2.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–1): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 190 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,846,097–143,846,504, 1 gene, copy number 5: AC239798.2.
- chr1:143,905,487–143,934,776, 1 gene, copy number 5 (within-gene range 3–10): AC246680.1.
- chr1:143,975,087–146,914,294, 83 genes, copy number 5 (broad region; genes not listed).
- chr1:235,104,180–235,344,532, 8 genes, copy number 5: AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1.
- chr1:235,336,806–235,362,540, 2 genes, copy number 5: AL391994.1, AL357556.1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 5: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 5 (within-gene range 2–5): TRGV5P, TRGV5.
- chr10:95,141,925–95,168,425, 1 gene, copy number 5: AL157834.4.
- chr14:22,163,238–22,507,723, 56 genes, copy number 5: TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34.
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr15:30,098,826–30,154,110, 5 genes, copy number 5–10: DNM1P28, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2.
- chr17:46,372,855–46,487,141, 1 gene, copy number 21: NSFP1.
- chr20:53,608,354–53,668,758, 2 genes, copy number 5 (within-gene range 4–5): AC005808.1, RNU7-14P.
- chr21:38,805,183–38,956,467, 6 genes, copy number 5: ETS2, AP001042.1, AP001042.2, AP001043.1, SNORA62, RPSAP64.
- chr22:18,636,445–18,719,341, 3 genes, copy number 5: CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:18,846,811–18,861,049, 1 gene, copy number 16 (within-gene range 1–16): AC008132.1.
- chr22:18,906,028–18,914,238, 1 gene, copy number 5 (within-gene range 2–5): DGCR6.

Autosomal genes at a single copy (total copy number 1): 3,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
